Gene-level copy-number profile of tumor specimen ALCH-B389-TTP1-A from ALCHEMIST case ALCH-B389, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,565 days).
Specimen ALCH-B389-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a71f0f71-dd8c-4da4-bd73-1c49b83cc694.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B389-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/97310ff2-5037-44bd-9d3f-34e652c290b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 1,559; copy number 2: 56,349; copy number 3: 418; copy number 4: 10; copy number 5: 6; copy number 6: 3; copy number 7: 5; copy number 12: 5; copy number 14: 2; copy number 16: 1; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,618,787–153,634,397, 4 genes (within-gene range 0–2): S100A13, AL162258.1, S100A1, AL162258.2.
- chr2:176,164,051–176,201,252, 7 genes (within-gene range 0–2): HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:124,887,410–124,887,549, 1 gene (within-gene range 0–2): RNU4-82P.
- chr12:34,164,773–34,166,954, 1 gene: TUBB8P4.
- chr14:35,447,003–35,447,625, 1 gene: AL133163.3.
- chr17:16,441,577–16,492,193, 1 gene (within-gene range 0–2): LRRC75A.
- chr17:22,090,743–22,332,410, 7 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:27,623,364–27,640,777, 1 gene (within-gene range 0–2): AC015688.4.
- chr17:27,629,798–27,649,560, 1 gene: LGALS9.
- chr17:80,169,992–80,209,331, 2 genes (within-gene range 0–2): CARD14, AC087741.1.
- chr20:56,468,585–56,526,152, 4 genes (within-gene range 0–2): RTF2, GCNT7, FAM209A, AL109806.1.
- chr22:18,636,445–18,653,617, 2 genes: CA15P2, PPP1R26P2.
- chr22:36,281,280–36,387,967, 3 genes (within-gene range 0–2): MYH9, MIR6819, Z82215.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr8:143,915,153–143,976,734, 2 genes, copy number 5: PLEC, MIR661.
- chr22:18,422,244–18,500,594, 1 gene, copy number 6 (within-gene range 4–6): FAM230A.
- chr22:18,501,794–18,625,289, 10 genes, copy number 5–19: FAM247B, GGTLC3, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.
- chr22:18,715,815–18,719,341, 1 gene, copy number 7: PPP1R26P4.
- chr22:21,341,595–21,396,590, 8 genes, copy number 5–16: PPP1R26P5, LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.
- chr22:50,669,804–50,669,901, 1 gene, copy number 6: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
